Surgical pathology report (de-identified scan), TCGA case TCGA-A4-7288, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-7288-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Kidney, right, radical nephrectomy:

Renal cell carcinoma, papillary type (type II), grade 3 (Fuhrman), 2 cm in greatest dimension involving the lower pole, confined to the kidney, and without invasion of perirenal fat or renal sinus fat.

Ureter, renal artery, and renal vein at surgical margin negative for malignancy.

Negative for lymphatic space invasion.

Non-neoplastic renal parenchyma shows mild arterionephrosclerosis.

No lymph nodes or adrenal gland present.

AJCC cancer classification: T1aNXMX.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Right kidney

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in a single formalin filled container labeled with the patient's name [REDACTED] 'right kidney' and consists of a [REDACTED] right nephrectomy specimen with attached Gerota's fascia and perinephric fat having overall dimensions of 17.0 x 8.5 x 6.5 cm. Extending from the hilum is a 4.0 cm in length by 0.4 cm in diameter segment of ureter with adjacent segments of vasculature. The specimen is inked. The capsule strips with ease to reveal an 8.5 x 6.0 x 4.5 cm kidney. The kidney is bivalved to reveal a 2.0 x 1.9 x 1.9 cm yellow tan hemorrhagic, variegated mass arising from the lower pole. This mass approaches to within 3.5 cm of the ureteral margin, 2.0 cm of the renal vein margin and 1.0 cm of the inked soft tissue margin. Additionally, this mass abuts, but does not grossly involve the urothelium. The calices and renal pelvis are lined by pink tan striated urothelium with no additional lesions. The cortex is red brown with distinct cortical medullary junction and non-blunted renal papilla. No adrenal gland or hilar lymph nodes are identified. Representative sections are submitted in five cassettes labeled [REDACTED] designated as follows: 1—ureteral and vasculature margins, en-face; 2—inked soft tissue margin, perpendicular; 3—mass to renal parenchyma and sinus fat; 4—remainder of mass; 5—uninvolved parenchyma. Additionally, a yellow and green cassette are submitted for genomic research each labeled [REDACTED]. An additional section of renal vein submitted in cassette 6 labeled [REDACTED].

Source: NCI Genomic Data Commons file 8867b595-f7f0-422d-844d-807b01196ea8 (TCGA-A4-7288.513D1DC1-CC1F-49A8-8843-FBC019C64DF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).